CGCI case HTMCP-03-06-02389 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c5789e82-9269-4bd7-9a24-ee7fceeb6239

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 41 years; Vital status: Dead; Days to death: 186 days.

Diagnoses (1)
1. Squamous cell carcinoma, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 41.1 years (15,002 days); Year of diagnosis: 2016; Method of diagnosis: Biopsy; AJCC clinical T: T1b2; AJCC clinical N: NX; AJCC clinical M: MX; FIGO stage: Stage IB2; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 186 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 15 days; Days to treatment end: 59 days; Treatment dose: 18.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 186 days; Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Nadir CD4 count: 560.
- Day 0: Weight: 51 kg; Height: 154 cm; BMI: 21.5; CD4 count: 376; Haart treatment indicator: Yes; HIV viral load: 34; Hormonal contraceptive use: Former User; Hysterectomy type: Not Performed; Menopause status: Perimenopausal; Pregnant at diagnosis: No.
- Day 0: Pregnancy outcome: Ectopic Pregnancy.
- Risk factors: HIV/AIDS.
- Comorbidities: HIV/AIDS.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02389-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02389-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02389-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Peri (6-12 months since last menstrual period); Weight kg at diagnosis: 51 kg; History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 06; Pregnancies count miscarriage: 00; Pregnancies count induced abortion: 00; Pregnancies count ectopic: 01; Pregnancies count stillbirth: 00; Total pregnancy count: 07; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Non-Keratinizing; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Year of HIV diagnosis: 2014; Nadir cd4 counts: 0560; HIV rna load at diagnosis: 000034; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes; Cd4 counts at diagnosis: 0376.
- Treatments, Treatment: Therapy regimen: Initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 18.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet02_20191105.xlsx (sheet validation DNAs), for sample HTMCP-03-06-02389-01A-01D-10409:
- % tumour top: not determined
- % tumour bottom: not determined

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet02_20191105.xlsx (sheet validation DNAs), for sample HTMCP-03-06-02389-10A-01D-10409:
- % tumour top: 0
- % tumour bottom: 0

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet_20191105.xlsx, for sample HTMCP-03-06-02389-01A-02D-10409:
- % tumour top: not determined
- % tumour bottom: not determined
